Surgical pathology report (de-identified scan), TCGA case TCGA-AG-4005, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-4005-01A (Primary Tumor).

Diagnosis:

Resected colon sample (of the rectum) with tumor-free oral, aboral and perirectal resection margins and including an ulcerated, moderately differentiated adenocarcinoma with infiltration of the perimuscular fatty tissue. There are several local lymph node metastases and adrenal metastases (on the left side). (G2, pT3, L1, V1, pN2, 7/40 pM1).

Source: NCI Genomic Data Commons file c104128f-face-4da8-8157-0c0bccefd9db (TCGA-AG-4005.86302433-C936-4213-84F3-63F2C5933686.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).